Gene-level copy-number profile of tumor specimen C3N-03417-01 from CPTAC case C3N-03417, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 67.8 years (24,766 days).
Specimen C3N-03417-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c99ccedc-ba81-4815-884d-f87e65918953.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03417-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/c6eeaaa5-cca5-43e3-be7e-2ab96eb38e5d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 1; copy number 2: 3; copy number 3: 9; copy number 4: 33,466; copy number 5: 925; copy number 6: 15,493; copy number 7: 757; copy number 8: 7,727; copy number 9: 3; copy number 10: 4.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–4): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr4:9,153,296–9,170,270, 2 genes: FAM86KP, ALG1L14P.
- chr4:9,210,657–9,212,249, 1 gene: USP17L10.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,838,125–12,841,357, 1 gene, copy number 9: PRAMEF30P.
- chr14:18,333,726–18,419,273, 4 genes, copy number 10: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr21:10,640,028–10,649,835, 2 genes, copy number 9: AF254982.1, IGHV1OR21-1.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
